Somatic mutation profile of tumor specimen TCGA-BS-A0TJ-01A (aliquot TCGA-BS-A0TJ-01A-11D-A10B-09) from TCGA case TCGA-BS-A0TJ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Tumor grade: G3; Age at diagnosis: 59.3 years (21,663 days).
Specimen TCGA-BS-A0TJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1480fd2-9c66-42f3-856b-91fc94726e1e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BS-A0TJ-10A (Blood Derived Normal), aliquot TCGA-BS-A0TJ-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7761db36-d342-43bd-b679-62e811ff18ed

The open-access MAF lists 858 somatic variants for this specimen: 654 protein-altering or splice-affecting, 179 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 421, Silent 179, Frame Shift Del 158, Nonsense Mutation 29, Frame Shift Ins 25, Intron 9, Splice Region 9, Splice Site 8, RNA 7, 3'UTR 6, In Frame Del 3, 5'UTR 2.

Variants (750 of 858; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 46/104 reads (44%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 31/64 reads (48%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- DMD | c.8010G>A p.W2670* | Nonsense Mutation (SNP) | VAF 5/136 reads (4%) | catalogued as rs1569186252, COSV58889776; ClinVar: pathogenic; called by muse, mutect2
- HNF1B | c.1561del p.Q521Sfs*70 | Frame Shift Del (DEL) | VAF 79/207 reads (38%) | catalogued as rs764042837; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- IQSEC2 | c.848del p.G283Afs*23 (on ENST00000642864 / NM_001111125.3; = p.G78Afs*23 on NM_015075.2) | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as rs782660318, COSV64726734; ClinVar: pathogenic; called by mutect2, pindel
- KCNQ2 | c.297-2A>G p.X99_splice | Splice Site (SNP) | VAF 12/39 reads (31%) | catalogued as rs796052615, CS131790, COSV60431604; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.3704del p.G1235Vfs*95 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | catalogued as rs1364500207, COSV99979040; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 58/144 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 78/224 reads (35%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 26/72 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1692C>G p.N564K (on ENST00000521381 / NM_181523.3; = p.N294K on NM_181504.4) | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs773686816, COSV57123079; ClinVar: likely pathogenic; called by muse, mutect2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 53/118 reads (45%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.1026+1G>A p.X342_splice | Splice Site (SNP) | VAF 29/59 reads (49%) | hotspot (GDC flag); catalogued as rs786201041, CS043794, CS110216, COSV64288702, COSV64289135, COSV64293873; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PXDN | c.2568del p.C857Afs*5 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | catalogued as rs558163499, CD117085; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RAD50 | c.2801del p.N934Ifs*6 | Frame Shift Del (DEL) | VAF 53/124 reads (43%) | catalogued as rs748536322; ClinVar: pathogenic; called by mutect2, varscan2
- SACS | c.6172del p.S2058Lfs*19 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs1214399996, CD056852, CD1111485; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TOP3A | c.2271del p.R758Gfs*15 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | catalogued as rs752838075; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA13 | c.1314G>A p.W438* | Nonsense Mutation (SNP) | VAF 29/89 reads (33%) | catalogued as COSV70025581; called by muse, mutect2, varscan2
- ABCA13 | c.4166G>A p.S1389N | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT tolerated (0.29); PolyPhen benign (0.045); catalogued as COSV70025586; called by muse, mutect2, varscan2
- ABCB9 | c.1985del p.P662Qfs*19 (on ENST00000280560 / NM_019625.4; = p.P619Qfs*19 on NM_019624.3) | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | catalogued as rs1169625873; called by mutect2, pindel, varscan2
- ABCC12 | c.4017A>C p.E1339D | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV60911313; called by muse, mutect2
- ABCC9 | c.2096A>T p.Q699L | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV53961884; called by muse, mutect2, varscan2
- ABHD16B | c.37G>A p.V13M | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.021); catalogued as COSV53861303; called by muse, mutect2
- ACAP1 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV50134030; called by muse, mutect2, varscan2
- ACTBL2 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 25/58 reads (43%) | catalogued as rs954378153, COSV70660955, COSV70661840; called by muse, mutect2, varscan2
- ADAL | c.651dup p.E218Rfs*11 | Frame Shift Ins (INS) | VAF 32/82 reads (39%) | catalogued as rs778831705; called by mutect2, varscan2
- ADAMTS15 | c.2285del p.T762Rfs*18 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as COSV54502676, COSV54510513; called by mutect2, pindel, varscan2
- ADAMTS5 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV53175245; called by muse, mutect2, varscan2
- ADAT1 | c.394A>G p.I132V | Missense Mutation (SNP) | VAF 80/203 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs752395808, COSV57185153; called by muse, mutect2, varscan2
- ADGRV1 | c.5321C>G p.A1774G | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.142); catalogued as COSV67977788; called by muse, mutect2, varscan2
- ADRB2 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60005120; called by muse, mutect2, varscan2
- AFAP1L2 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.2); catalogued as rs147328544; called by muse, mutect2, varscan2
- AFF2 | c.1444G>A p.G482R | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs782182585, COSV53975179; called by muse, mutect2, varscan2
- AGBL5 | c.2069G>T p.R690L | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as rs772756784, COSV59935409; called by muse, mutect2, varscan2
- AHNAK2 | c.4125C>A p.D1375E | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.147); catalogued as COSV60906847; called by muse, mutect2, varscan2
- AHNAK2 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.034); catalogued as COSV60906855; called by muse, mutect2, varscan2
- AK9 | c.5236G>A p.G1746S | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV101413948, COSV69848745; called by muse, mutect2, varscan2
- AKAP10 | c.1002G>T p.Q334H | Missense Mutation (SNP) | VAF 64/122 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV56729993; called by muse, mutect2, varscan2
- AL163540.1 | n.332A>C | Splice Region (SNP) | VAF 89/348 reads (26%) | catalogued as rs1206022416; called by muse, mutect2, varscan2
- ALG13 | c.1881G>A p.M627I | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV52634913; called by muse, mutect2, varscan2
- AMOTL2 | c.156G>T p.Q52H | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.556); catalogued as COSV51437604; called by muse, mutect2, varscan2
- ANGEL1 | c.1453C>A p.L485M | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51871755; called by muse, mutect2, varscan2
- ANK2 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52144257; called by muse, mutect2, varscan2
- ANKRD33 | c.230G>A p.R77H (on ENST00000340970 / NM_001304459.2; = p.R212H on NM_182608.4) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs751233923, COSV56604835; called by muse, mutect2
- ANKRD35 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.22); catalogued as COSV62909427; called by muse, mutect2, varscan2
- ANXA11 | c.1026_1027dup p.Q343Lfs*51 | Frame Shift Ins (INS) | VAF 54/150 reads (36%) | catalogued as rs756281507; called by mutect2, varscan2
- AP2A1 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV62817197, COSV62820811; called by muse, mutect2, varscan2
- APOBEC3D | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 94/201 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs746506547, COSV53325418; called by muse, mutect2, varscan2
- ARHGAP21 | c.2132A>G p.Q711R | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV57601756; called by muse, mutect2, varscan2
- ARHGEF28 | c.3285G>T p.W1095C | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55246640; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID1B | c.264_266dup p.H89dup | In Frame Ins (INS) | VAF 16/48 reads (33%) | catalogued as rs752012879; called by mutect2, varscan2
- ARID4A | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs1180580215, COSV62161861; called by muse, mutect2, varscan2
- ASB2 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV60110211; called by muse, mutect2, varscan2
- ASB7 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.898); catalogued as rs1240121997, COSV58403240; called by muse, mutect2, varscan2
- ASPSCR1 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as rs368957042; called by muse, mutect2, varscan2
- ASTN2 | c.2137C>T p.Q713* (on ENST00000313400 / NM_001365069.1; = p.Q662* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 6/88 reads (7%) | catalogued as COSV57748058; called by muse, mutect2
- ATP6V0A1 | c.1997A>C p.K666T | Missense Mutation (SNP) | VAF 154/334 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.213); catalogued as COSV52870537; called by muse, mutect2, varscan2
- ATRX | c.5407C>T p.R1803C | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64870857; called by muse, mutect2, varscan2
- BAZ1A | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 80/239 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs767097767, COSV62408832; called by muse, mutect2, varscan2
- BAZ1A | c.869A>G p.N290S | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371707800, COSV62408839; called by muse, mutect2, varscan2
- BBS12 | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58561010; called by muse, mutect2, varscan2
- BCAN | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs757148760, COSV61255311; called by muse, mutect2, varscan2
- BCLAF1 | c.385T>G p.S129A | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.817); catalogued as COSV62140144; called by muse, mutect2, varscan2
- BCOR | c.1919T>G p.L640R | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV60698852; called by muse, mutect2, varscan2
- BEND3 | c.2293G>A p.G765R | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64679904; called by muse, mutect2, varscan2
- BEND5 | c.1052del p.K351Rfs*15 | Frame Shift Del (DEL) | VAF 88/194 reads (45%) | catalogued as rs756345162, COSV65718189; called by mutect2, varscan2
- BFSP2 | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.185); catalogued as COSV56586094; called by muse, mutect2
- BICD1 | c.2341C>T p.R781* | Nonsense Mutation (SNP) | VAF 8/71 reads (11%) | catalogued as rs749713234, COSV55673974; called by muse, mutect2, varscan2
- BMP1 | c.2153G>A p.C718Y | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60475963; called by muse, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 9/20 reads (45%) | catalogued as rs763134487; called by mutect2, varscan2
- BRWD3 | c.3418del p.A1140Lfs*42 | Frame Shift Del (DEL) | VAF 40/127 reads (31%) | catalogued as COSV100956344; called by pindel, varscan2
- C1GALT1C1 | c.752T>C p.V251A | Missense Mutation (SNP) | VAF 107/279 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV58973690; called by muse, mutect2, varscan2
- C3 | c.2976G>T p.E992D | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55568123; called by muse, mutect2, varscan2
- C7orf25 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63273084; called by muse, mutect2, varscan2
- C7orf50 | c.535del p.L179Cfs*136 | Frame Shift Del (DEL) | VAF 8/12 reads (67%) | catalogued as rs750339990; called by mutect2, varscan2
- C7orf61 | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.25); catalogued as COSV55723336; called by muse, mutect2, varscan2
- CACNA1C | c.2635G>A p.A879T | Missense Mutation (SNP) | VAF 19/216 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1568641351, COSV59695058; ClinVar: uncertain significance; called by muse, mutect2
- CACNA1F | c.3956C>T p.T1319I | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59902843; called by muse, mutect2, varscan2
- CACNG4 | c.518A>G p.E173G | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as COSV50924064; called by muse, mutect2
- CAPN12 | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61014544; called by muse, mutect2, varscan2
- CARNMT1 | c.1097del p.N366Tfs*10 | Frame Shift Del (DEL) | VAF 108/288 reads (38%) | catalogued as rs769078744; called by mutect2, pindel, varscan2
- CASP8 | c.1260G>C p.W420C (on ENST00000432109 / NM_033355.3; = p.W437C on NM_001228.4) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51844981; called by muse, mutect2, varscan2
- CAT | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs764570816, COSV53810218; called by muse, mutect2, varscan2
- CC2D1A | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs773188635, COSV58780974; called by muse, mutect2, varscan2
- CCAR2 | c.1199C>T p.T400I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199704953, COSV57904140; called by muse, mutect2, varscan2
- CCDC151 | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); catalogued as COSV62697077; called by muse, mutect2, varscan2
- CCDC24 | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 25/56 reads (45%) | catalogued as rs774483728, COSV62209724; called by muse, mutect2, varscan2
- CCDC78 | c.827C>A p.A276E | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.359); catalogued as COSV53494728; called by muse, mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 34/86 reads (40%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CDH15 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as rs1220435144, COSV57021698; called by muse, mutect2, varscan2
- CDH4 | c.2168G>A p.G723D | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.972); catalogued as COSV64641001; called by muse, mutect2, varscan2
- CEP68 | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs766897498, COSV53123265; called by muse, mutect2, varscan2
- CERKL | c.1443+2T>C p.X481_splice (on ENST00000339098 / NM_001030311.2; = p.X455_splice on NM_201548.5) | Splice Site (SNP) | VAF 76/180 reads (42%) | catalogued as COSV59202634; called by muse, mutect2, varscan2
- CERKL | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1344137236, COSV59202644; called by muse, mutect2, varscan2
- CES3 | c.618G>T p.L206F | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57592587; called by muse, mutect2, varscan2
- CFAP43 | c.1418C>T p.S473L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as rs747096752, COSV53376033; called by muse, mutect2, varscan2
- CHEK1 | c.676del p.T226Hfs*14 | Frame Shift Del (DEL) | VAF 24/55 reads (44%) | catalogued as rs757716680, COSV54024545; called by mutect2, varscan2
- CHRNA6 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs141518931, CM1410520; called by muse, mutect2, varscan2
- CHST4 | c.19del p.M7* | Frame Shift Del (DEL) | VAF 50/136 reads (37%) | catalogued as rs745406065; called by mutect2, pindel, varscan2
- CIC | c.4004C>A p.P1335H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV50546641; called by muse, mutect2, varscan2
- CIC | c.4682C>T p.S1561L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV50546654; called by muse, mutect2
- CIITA | c.1654C>T p.R552C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs897543782, COSV60853612; called by muse, mutect2, varscan2
- CLUH | c.3321C>T p.D1107= (on ENST00000435359; = p.D1146= on NM_015229.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 8/17 reads (47%) | catalogued as rs762314998, COSV70927598; called by muse, mutect2, varscan2
- COL4A2 | c.4275dup p.G1426Rfs*30 | Frame Shift Ins (INS) | VAF 14/48 reads (29%) | catalogued as rs34603892; called by mutect2, varscan2
- COLQ | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV67524075; called by muse, mutect2, varscan2
- COQ6 | c.86G>C p.G29A | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV53177783; called by muse, mutect2, varscan2
- CPEB3 | c.188del p.P63Rfs*19 | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | catalogued as rs751359395; called by mutect2, pindel, varscan2
- CPSF1 | c.3055C>T p.R1019C | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs782785338, COSV58232048; called by muse, mutect2, varscan2
- CRYGB | c.422G>T p.R141M | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV53679656, COSV99649954; called by muse, mutect2, varscan2
- CSMD2 | c.4087A>G p.S1363G | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV53875702; called by muse, mutect2, varscan2
- CSNK1A1 | c.820T>C p.Y274H | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV55792492; called by muse, mutect2, varscan2
- CTNNBL1 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 85/228 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as rs746327161, COSV63743473; called by muse, mutect2, varscan2
- CTSL | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 78/146 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58245601; called by muse, mutect2, varscan2
- CTTNBP2 | c.1546G>T p.G516W | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV50389270; called by muse, mutect2
- CUBN | c.1847G>A p.C616Y | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64707161; called by muse, mutect2, varscan2
- CUL9 | c.487del p.R163Gfs*46 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | catalogued as COSV52724909; called by mutect2, pindel, varscan2
- CUX1 | c.1738G>T p.G580* | Nonsense Mutation (SNP) | VAF 31/74 reads (42%) | catalogued as COSV52890050; called by muse, mutect2, varscan2
- CWF19L2 | c.526A>T p.T176S | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV56508075; called by muse, mutect2
- CYP2S1 | c.295A>G p.S99G | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs1568399120, COSV59504907; called by muse, mutect2, varscan2
- DAPK1 | c.3542C>T p.A1181V | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV63783728; called by muse, mutect2, varscan2
- DCAF4L1 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV60786341; called by muse, mutect2, varscan2
- DDHD2 | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 96/227 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763476356, COSV68157058; called by muse, mutect2, varscan2
- DDO | c.965C>T p.A322V (on ENST00000368924 / NM_001368172.1; = p.A263V on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV64469597; called by muse, mutect2, varscan2
- DDR2 | c.1828C>T p.L610F | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63369040; called by muse, mutect2
- DDX5 | c.1618T>C p.Y540H | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.054); catalogued as COSV56747307; called by muse, mutect2, varscan2
- DEPDC5 | c.2756G>A p.R919H (on ENST00000400246; = p.R988H on NM_014662.5) | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1569088819, COSV56690455; called by muse, mutect2, varscan2
- DIPK1B | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs371582245; called by muse, mutect2, varscan2
- DIXDC1 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs1027236169, COSV100180031, COSV59460966; called by muse, mutect2, varscan2
- DLG3 | c.443G>A p.G148D | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52079611; called by muse, mutect2
- DLL1 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as rs752173329, COSV64536636; called by muse, mutect2, varscan2
- DMXL1 | c.7706G>A p.R2569H | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs750990275, COSV60704181; called by muse, mutect2, varscan2
- DNAH5 | c.6040G>T p.G2014* | Nonsense Mutation (SNP) | VAF 55/122 reads (45%) | catalogued as COSV54202153, COSV54261997; called by muse, mutect2, varscan2
- DNAI4 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1349438531, COSV63083473; called by muse, mutect2, varscan2
- DNMBP | c.1366T>C p.Y456H | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.459); catalogued as COSV60619950; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 26/171 reads (15%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK5 | c.1118T>C p.I373T | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs150699795; called by muse, mutect2, varscan2
- DOCK7 | c.988A>T p.I330F | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV51994865, COSV52022892; called by muse, mutect2, varscan2
- DOP1B | c.155T>C p.L52P | Missense Mutation (SNP) | VAF 74/188 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV54279414; called by muse, mutect2, varscan2
- DSG2 | c.1514C>T p.T505I | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV55196487; called by muse, mutect2, varscan2
- DVL3 | c.745A>G p.T249A | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV57454683; called by muse, mutect2, varscan2
- DYSF | c.4913C>A p.P1638H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50266604; called by muse, mutect2, varscan2
- EAF1 | c.335+1G>A p.X112_splice | Splice Site (SNP) | VAF 43/90 reads (48%) | catalogued as COSV67541757; called by muse, mutect2, varscan2
- EDC4 | c.725C>A p.P242H | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV62765335; called by muse, mutect2, varscan2
- EEF1B2 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs367973620; called by muse, mutect2, varscan2
- EGR1 | c.1000del p.H334Tfs*198 | Frame Shift Del (DEL) | VAF 30/84 reads (36%) | catalogued as rs746692720; called by mutect2, pindel, varscan2
- EIF3I | c.298G>A p.G100S | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs750288369, COSV59083899; called by muse, mutect2, varscan2
- EMILIN3 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.346); catalogued as rs562547961, COSV60035001; called by muse, mutect2, varscan2
- ENAH | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52864785; called by muse, mutect2, varscan2
- EP400 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs1172065003, COSV57761858; called by muse, mutect2, varscan2
- EPHA3 | c.2249G>A p.R750Q | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs780417089, COSV60692867, COSV60703794; called by muse, mutect2, varscan2
- ERN1 | c.1523G>A p.G508D | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV70500206; called by muse, mutect2, varscan2
- EWSR1 | c.1714C>T p.R572W | Missense Mutation (SNP) | VAF 136/322 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV58421349; called by muse, mutect2, varscan2
- EXPH5 | c.408G>T p.K136N | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1395249817, COSV56198595; called by muse, mutect2
- EXPH5 | c.278dup p.N93Kfs*2 | Frame Shift Ins (INS) | VAF 75/228 reads (33%) | catalogued as rs1305598119; called by mutect2, pindel, varscan2
- EXT1 | c.2039A>C p.E680A | Missense Mutation (SNP) | VAF 18/285 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as COSV65474555; called by muse, mutect2
- F7 | c.610dup p.R204Kfs*77 | Frame Shift Ins (INS) | VAF 34/85 reads (40%) | catalogued as rs1288996601; called by mutect2, pindel, varscan2
- FAM47C | c.599del p.P200Rfs*625 | Frame Shift Del (DEL) | VAF 27/73 reads (37%) | catalogued as COSV63726734; called by mutect2, pindel, varscan2
- FAT4 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.653); catalogued as COSV67880854; called by muse, mutect2
- FBRS | c.51G>A p.P17= (on ENST00000287468; = p.P537= on NM_001105079.3) | Splice Region (SNP) | VAF 7/13 reads (54%) | catalogued as rs768842699, COSV54914650; called by muse, mutect2, varscan2
- FBXO31 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs187880966; called by muse, mutect2, varscan2
- FEM1C | c.778del p.R260Efs*7 | Frame Shift Del (DEL) | VAF 17/163 reads (10%) | catalogued as rs1561556190; called by mutect2, pindel, varscan2
- FER1L6 | c.3442G>A p.D1148N | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs772356288, COSV67547773, COSV67548659; called by muse, mutect2, varscan2
- FES | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs138511924; called by muse, mutect2, varscan2
- FLG | c.448A>G p.K150E | Missense Mutation (SNP) | VAF 154/382 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as rs756351291, COSV64235927; called by muse, mutect2, varscan2
- FLNA | c.7273C>T p.H2425Y (on ENST00000369850 / NM_001110556.2; = p.H2417Y on NM_001456.3) | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as rs1557175435, COSV61036665; called by muse, mutect2, varscan2
- FNDC3B | c.1795A>G p.N599D | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV61036793; called by muse, mutect2
- FPGT-TNNI3K | c.619C>A p.R207S | Missense Mutation (SNP) | VAF 81/194 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.922); catalogued as COSV58544729; called by muse, mutect2, varscan2
- FPR1 | c.825G>A p.M275I | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV59050889; called by muse, mutect2
- FSD1 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as rs770007894, COSV55694412; called by muse, mutect2
- FSIP1 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 136/322 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV63223147; called by muse, mutect2, varscan2
- FUBP1 | c.133del p.I45Lfs*9 | Frame Shift Del (DEL) | VAF 48/121 reads (40%) | catalogued as COSV53935006; called by mutect2, pindel, varscan2
- GALNT15 | c.1400A>G p.K467R | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV60215089; called by muse, mutect2, varscan2
- GALNTL6 | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.913); catalogued as rs1266920736, COSV72488918; called by muse, mutect2, varscan2
- GBP5 | c.1457del p.K486Rfs*7 | Frame Shift Del (DEL) | VAF 57/182 reads (31%) | catalogued as rs779147050; called by mutect2, pindel, varscan2
- GCC2 | c.2135del p.L712Cfs*16 | Frame Shift Del (DEL) | VAF 34/84 reads (40%) | catalogued as rs777909420; called by mutect2, pindel, varscan2
- GCN1 | c.3343G>A p.A1115T | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1327955106, COSV56103171; called by muse, mutect2
- GGA2 | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs765809092, COSV59167295; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 17/44 reads (39%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GLI3 | c.1958C>T p.P653L | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.079); catalogued as rs141220299, COSV101229954; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GNPAT | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 78/174 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs750828898, COSV64152944; called by muse, mutect2, varscan2
- GOLGA3 | c.2773G>T p.A925S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV52624771, COSV99213296; called by muse, mutect2, varscan2
- GOLGA5 | c.457T>C p.S153P | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs748009930, COSV50831959; called by muse, mutect2, varscan2
- GRIA2 | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 32/475 reads (7%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV52381409; called by muse, mutect2
- GRIK5 | c.1933G>A p.V645M | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555872788, COSV53474359; called by muse, mutect2, varscan2
- GRK2 | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV57750546; called by muse, mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 21/28 reads (75%) | catalogued as rs754199513; called by mutect2, varscan2
- GTF2E2 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 78/185 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV63478013; called by muse, mutect2, varscan2
- HCN4 | c.2098C>T p.R700* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV56081039; called by muse, mutect2, varscan2
- HDAC4 | c.724A>G p.R242G | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61858704; called by muse, mutect2
- HDAC6 | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782393826, COSV61927334, COSV61930227; called by muse, mutect2, varscan2
- HECTD4 | c.9718del p.A3240Rfs*26 | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | catalogued as rs754540615; called by mutect2, pindel, varscan2
- HECW2 | c.2505G>A p.W835* | Nonsense Mutation (SNP) | VAF 6/81 reads (7%) | catalogued as COSV53648021; called by muse, mutect2
- HIVEP1 | c.3994G>A p.A1332T | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.767); catalogued as COSV65098432; called by muse, mutect2
- HOXA11 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 12/24 reads (50%) | catalogued as COSV50052788; called by muse, mutect2, varscan2
- HOXA7 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV54216604; called by muse, mutect2, varscan2
- HSP90AB1 | c.1478A>C p.Q493P | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as COSV62333099; called by muse, mutect2
- HYDIN | c.3362del p.N1121Tfs*3 | Frame Shift Del (DEL) | VAF 22/128 reads (17%) | catalogued as rs764203047; called by pindel, varscan2
- IFFO1 | c.1089del p.R364Gfs*47 (on ENST00000396840 / NM_001330324.2; = p.R367Gfs*47 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs750779916, COSV60737300; called by mutect2, pindel, varscan2
- IHH | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs142182864; called by muse, mutect2, varscan2
- IL10RA | c.1381G>T p.G461C | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV57139637; called by muse, mutect2, varscan2
- IL20RA | c.579G>A p.T193= | Splice Region (SNP) | VAF 72/165 reads (44%) | catalogued as rs375320839, COSV57356204; called by muse, mutect2, varscan2
- INHBB | c.1160A>G p.D387G | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); catalogued as COSV54677247; called by muse, varscan2
- INO80B | c.25A>T p.S9C | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.439); catalogued as COSV51968018; called by muse, mutect2, varscan2
- INO80E | c.42del p.K14Nfs*5 | Frame Shift Del (DEL) | VAF 18/30 reads (60%) | catalogued as rs762875806; called by mutect2, varscan2
- INPP5D | c.1517G>A p.C506Y (on ENST00000445964 / NM_001017915.3; = p.C505Y on NM_005541.5) | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.328); catalogued as COSV64035220; called by muse, mutect2, varscan2
- INTS1 | c.4987C>A p.L1663I | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV67176257; called by muse, mutect2, varscan2
- INTS1 | c.1477C>T p.R493W | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766116950, COSV67176261; called by muse, mutect2, varscan2
- INTS5 | c.1531C>T p.R511W | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs374081365, COSV100399661; called by muse, mutect2, varscan2
- IRX1 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV57357791; called by muse, mutect2, varscan2
- ITGA2 | c.502+1G>A p.X168_splice | Splice Site (SNP) | VAF 77/182 reads (42%) | catalogued as rs748653916, COSV56855871; called by muse, mutect2, varscan2
- ITGA5 | c.2810A>G p.H937R | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53215188; called by muse, mutect2, varscan2
- ITGAD | c.1267del p.A423Pfs*52 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as rs779349944; called by mutect2, pindel, varscan2
- ITGAD | c.2230del p.Q744Rfs*47 | Frame Shift Del (DEL) | VAF 46/110 reads (42%) | catalogued as rs772591197; called by mutect2, pindel, varscan2
- ITGAL | c.1531C>T p.Q511* | Nonsense Mutation (SNP) | VAF 33/55 reads (60%) | catalogued as COSV63319935; called by muse, mutect2, varscan2
- ITSN2 | c.2932G>A p.A978T | Missense Mutation (SNP) | VAF 73/171 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV61943448; called by muse, mutect2, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 46/115 reads (40%) | catalogued as rs755650243; called by mutect2, pindel, varscan2
- JPH2 | c.1798G>A p.A600T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.05); catalogued as rs777312604, COSV65901676; called by mutect2, varscan2
- KANK1 | c.3922G>A p.A1308T | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781145505, COSV66527230; called by muse, mutect2, varscan2
- KBTBD8 | c.1504T>C p.Y502H | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55126340; called by muse, mutect2, varscan2
- KCNB1 | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as rs1391326211, COSV65565804; called by muse, mutect2, varscan2
- KCNC2 | c.1530G>T p.K510N | Missense Mutation (SNP) | VAF 73/145 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV54361588; called by muse, mutect2, varscan2
- KCTD13 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV58156369; called by muse, mutect2, varscan2
- KCTD14 | c.500G>A p.S167N | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV62000989; called by muse, mutect2, varscan2
- KIAA0586 | c.4427C>T p.P1476L (on ENST00000619416 / NM_001244190.2; = p.P1415L on NM_014749.5) | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs370303493; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF12 | c.982G>A p.D328N (on ENST00000640217; = p.D190N on NM_138424.1) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV65116579; called by muse, mutect2
- KIF13B | c.4031T>C p.L1344P | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as COSV72954252; called by muse, mutect2, varscan2
- KIF1B | c.4133G>T p.G1378V (on ENST00000377086 / NM_001365952.1; = p.G1332V on NM_015074.3) | Missense Mutation (SNP) | VAF 67/164 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV55803016; called by muse, mutect2, varscan2
- KIF26B | c.1510C>A p.P504T | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63636219; called by muse, mutect2, varscan2
- KIT | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV55387302, COSV55393138, COSV99853968; called by muse, mutect2, varscan2
- KLC3 | c.878C>T p.T293M | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754333103, COSV67266496; called by muse, mutect2, varscan2
- KLHL34 | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV65278670; called by muse, mutect2, varscan2
- KLHL5 | c.1566A>C p.R522S | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV54671199; called by muse, mutect2
- KNOP1 | c.957del p.G320Afs*8 | Frame Shift Del (DEL) | VAF 46/378 reads (12%) | catalogued as rs759734033, COSV54927684; called by mutect2, varscan2
- KPRP | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV64220864; called by muse, mutect2
- KRT5 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 89/195 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as rs766857995, COSV52858670; called by muse, varscan2
- KRTAP10-8 | c.592T>C p.C198R | Missense Mutation (SNP) | VAF 81/222 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV58165831; called by muse, mutect2, varscan2
- KRTAP5-8 | c.41G>A p.C14Y | Missense Mutation (SNP) | VAF 64/95 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV68324377; called by muse, mutect2, varscan2
- LAMA1 | c.7748C>T p.A2583V | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as rs141247075, COSV67542121; called by muse, mutect2, varscan2
- LAMA2 | c.5291A>G p.E1764G | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs141950826; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMB4 | c.26del p.L9Cfs*43 | Frame Shift Del (DEL) | VAF 35/184 reads (19%) | catalogued as rs747409331; called by mutect2, pindel, varscan2
- LILRB5 | c.1499C>T p.A500V (on ENST00000449561 / NM_001081442.3; = p.A499V on NM_006840.5) | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.248); catalogued as rs1043921231, COSV60254253, COSV60259176; called by muse, mutect2, varscan2
- LLGL2 | c.3052G>T p.G1018* (on ENST00000392550 / NM_001031803.2; = p.A1003= on NM_004524.3) | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as COSV51341780; called by muse, mutect2, varscan2
- LMO3 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV53780849; called by muse, mutect2, varscan2
- LMX1B | c.479A>G p.E160G | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.059); catalogued as COSV62737943; called by muse, mutect2
- LPL | c.941G>A p.G314D | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60929854; called by muse, mutect2, varscan2
- LRRC28 | c.1073A>G p.Q358R | Missense Mutation (SNP) | VAF 69/203 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV57335161; called by muse, mutect2, varscan2
- LRRC41 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV58438817; called by muse, mutect2, varscan2
- LRRC46 | c.635G>T p.R212M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as COSV51634785; called by muse, mutect2, varscan2
- LSG1 | c.520A>C p.S174R | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54568370; called by muse, mutect2, varscan2
- MAGEA10 | c.501T>A p.N167K | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.066); catalogued as COSV54882648; called by muse, mutect2, varscan2
- MAGI1 | c.2700G>A p.A900= (on ENST00000402939 / NM_001033057.2; = p.A928= on NM_004742.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 31/116 reads (27%) | catalogued as rs771285835, COSV58313101; called by muse, mutect2, varscan2
- MAN1A1 | c.1484A>G p.Q495R | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV63786383; called by muse, mutect2, varscan2
- MAP1B | c.6253G>A p.V2085M | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs999464682, COSV57093385; called by muse, mutect2
- MAP3K4 | c.4267G>A p.D1423N | Missense Mutation (SNP) | VAF 59/113 reads (52%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.923); catalogued as COSV62329937; called by muse, mutect2, varscan2
- MAP4K1 | c.80C>T p.T27M | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1302260800, COSV50263675; called by muse, mutect2, varscan2
- MAPT | c.766G>A p.G256S (on ENST00000262410 / NM_001377265.1; = p.G181S on NM_016835.4) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.017); catalogued as rs762327535, COSV52236686; called by muse, mutect2, varscan2
- MAST4 | c.7532G>A p.G2511D (on ENST00000403625 / NM_001164664.2; = p.G2322D on NM_015183.3) | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.571); catalogued as rs1205334757, COSV55114732; called by muse, mutect2, varscan2
- MATN2 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370342485; called by muse, mutect2, varscan2
- MCM6 | c.1268C>T p.A423V | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs771453730, COSV51464743; called by muse, mutect2, varscan2
- MCM8 | c.2246T>C p.L749P | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); catalogued as COSV54509966; called by muse, mutect2, varscan2
- MED12 | c.1058C>A p.P353H | Missense Mutation (SNP) | VAF 76/199 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61330106; called by muse, varscan2
- MED14 | c.3188C>T p.A1063V | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV61355704; called by muse, mutect2, varscan2
- MED24 | c.2575C>T p.R859* | Nonsense Mutation (SNP) | VAF 41/99 reads (41%) | catalogued as rs778352722, COSV56639896; called by muse, mutect2, varscan2
- MED24 | c.2056_2057del p.K686Vfs*47 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | catalogued as COSV62416844; called by mutect2, pindel, varscan2
- MGAM | c.2164T>C p.Y722H | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV72073520; called by muse, mutect2, varscan2
- MIB2 | c.1987C>T p.R663W | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs199626113, COSV61542304; called by muse, mutect2, varscan2
- MICAL3 | c.4238G>A p.R1413H | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs753011921, COSV71588030; called by muse, mutect2
- MICALL1 | c.1811C>A p.P604H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53239182; called by muse, mutect2, varscan2
- MIDEAS | c.2937G>A p.S979= | Splice Region (SNP) | VAF 40/100 reads (40%) | catalogued as rs1412434883, COSV54092373; called by muse, mutect2, varscan2
- MIER2 | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs758044102, COSV53393898; called by muse, mutect2, varscan2
- MIF4GD | c.628C>T p.P210S (on ENST00000325102 / NM_001370592.1; = p.P244S on NM_020679.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV55452803; called by muse, mutect2
- MINPP1 | c.792dup p.V265Sfs*11 | Frame Shift Ins (INS) | VAF 15/38 reads (39%) | catalogued as rs1487068341; called by mutect2, varscan2
- MIS18BP1 | c.2068del p.S690Vfs*10 | Frame Shift Del (DEL) | VAF 31/88 reads (35%) | catalogued as rs750307488; called by mutect2, varscan2
- MLC1 | c.135del p.C46Afs*12 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | catalogued as CD151534; called by mutect2, pindel, varscan2
- MMS22L | c.1808C>T p.A603V | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as COSV51516398; called by muse, mutect2, varscan2
- MORC2 | c.1813-3del | Splice Region (DEL) | VAF 46/100 reads (46%) | catalogued as rs777649506, COSV53202254; called by mutect2, varscan2
- MOSPD1 | c.152A>G p.K51R | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.936); catalogued as COSV66189063; called by muse, mutect2, varscan2
- MRC2 | c.4064G>A p.G1355E | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.371); catalogued as rs763097558, COSV57636298; called by mutect2, varscan2
- MROH1 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs185394696; called by muse, mutect2, varscan2
- MRPS33 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 38/376 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61341061; called by muse, mutect2
- MRPS7 | c.572G>A p.C191Y | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV55452797; called by muse, mutect2, varscan2
- MTHFR | c.472G>T p.G158* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV56737756; called by muse, mutect2, varscan2
- MUC16 | c.1601C>T p.T534I | Missense Mutation (SNP) | VAF 68/163 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV67442373; called by muse, mutect2, varscan2
- MUC17 | c.5545C>T p.P1849S | Missense Mutation (SNP) | VAF 86/176 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1456489822, COSV60279259, COSV60293442; called by muse, mutect2, varscan2
- MYBPC2 | c.1937G>A p.R646H | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV63093142; called by muse, mutect2
- MYO10 | c.3667G>A p.G1223R | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434873123, COSV57016082, COSV57017061; called by muse, mutect2, varscan2
- MYO15A | c.8276G>A p.R2759Q | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs374534318; called by muse, mutect2, varscan2
- MYO18A | c.2226A>T p.T742= | Splice Region (SNP) | VAF 13/38 reads (34%) | catalogued as COSV62862086; called by muse, mutect2, varscan2
- MYO1E | c.213G>T p.K71N | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); catalogued as COSV55682169; called by muse, mutect2, varscan2
- MYO7A | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1250301241, COSV68683267, COSV68686873; called by muse, mutect2, varscan2
- MYT1 | c.1421del p.P474Qfs*4 | Frame Shift Del (DEL) | VAF 17/89 reads (19%) | catalogued as COSV60505657; called by mutect2, pindel, varscan2
- NAV3 | c.4707G>T p.E1569D | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV99893752; called by mutect2, varscan2
- NBEA | c.6914C>A p.T2305N | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV59757811; called by muse, mutect2, varscan2
- NBR1 | c.2236del p.L746Wfs*50 | Frame Shift Del (DEL) | VAF 35/92 reads (38%) | catalogued as rs34660735; called by mutect2, pindel, varscan2
- NCOA5 | c.1732C>T p.H578Y | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.495); catalogued as COSV51642180; called by muse, mutect2
- NDOR1 | c.1622G>A p.G541E (on ENST00000371521 / NM_001144026.3; = p.G525E on NM_014434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.121); catalogued as COSV61286202; called by muse, mutect2, varscan2
- NDST4 | c.1961C>T p.T654I | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as rs1479321258, COSV52107954; called by muse, mutect2, varscan2
- NDUFA2 | c.266G>C p.R89T | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV52798889; called by muse, mutect2, varscan2
- NEIL1 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1428879515, COSV61833049; called by muse, mutect2, varscan2
- NEXN | c.2012T>C p.I671T | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs747781785, COSV53925740; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFATC2IP | c.583C>A p.L195M | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100297620, COSV57909690; called by muse, mutect2, varscan2
- NGEF | c.743G>T p.R248M | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV50914138, COSV50929046; called by muse, mutect2, varscan2
- NKAP | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.973); catalogued as rs1486378790, COSV65055893; called by muse, mutect2, varscan2
- NLGN2 | c.649G>T p.G217W | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57208813; called by muse, mutect2, varscan2
- NLGN3 | c.1850G>A p.R617Q (on ENST00000358741 / NM_181303.2; = p.R597Q on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62441528; called by muse, mutect2, varscan2
- NOC3L | c.1841G>A p.R614H | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs149958947; called by muse, mutect2, varscan2
- NOL12 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs371438425; called by muse, mutect2, varscan2
- NOL6 | c.2167C>G p.R723G | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.405); catalogued as rs35135082, COSV53038908; called by muse, mutect2, varscan2
- NOMO1 | c.3016C>T p.R1006C | Missense Mutation (SNP) | VAF 15/370 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772146601, COSV55056818; called by muse, mutect2
- NOS1 | c.2027del p.G676Afs*64 | Frame Shift Del (DEL) | VAF 34/102 reads (33%) | catalogued as rs746543323; called by mutect2, pindel, varscan2
- NPAP1 | c.1966C>T p.P656S | Missense Mutation (SNP) | VAF 94/204 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV61504030; called by muse, mutect2, varscan2
- NR2C2 | c.839T>C p.V280A (on ENST00000393102; = p.V299A on NM_003298.5) | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as COSV60144443; called by muse, mutect2
- NR2F2 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV67683079, COSV67684038; called by muse, mutect2
- NR4A2 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59892472; called by muse, mutect2, varscan2
- NRXN1 | c.1879T>G p.F627V | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV58434988; called by muse, mutect2, varscan2
- NUDC | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV57670764; called by muse, mutect2, varscan2
- NUP93 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs377453680; called by muse, mutect2, varscan2
- NUP98 | c.4552G>T p.D1518Y (on ENST00000359171 / NM_001365126.1; = p.D1501Y on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV61428163; called by muse, mutect2, varscan2
- NXF1 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.791); catalogued as COSV53671873; called by muse, mutect2
- OGFR | c.316A>G p.N106D | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.998); catalogued as COSV51696373; called by muse, mutect2, varscan2
- OLFM2 | c.781C>A p.L261M | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.793); catalogued as COSV53428331; called by muse, mutect2, varscan2
- OR2AT4 | c.121C>A p.L41I | Missense Mutation (SNP) | VAF 74/175 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.345); catalogued as COSV59406258; called by muse, mutect2, varscan2
- OR2T3 | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 87/196 reads (44%) | catalogued as rs546380813, COSV62081673; called by muse, mutect2, varscan2
- OR8H3 | c.724G>A p.V242I | Missense Mutation (SNP) | VAF 100/245 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs186768016, COSV57907283; called by muse, mutect2, varscan2
- ORC1 | c.1429C>T p.R477* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV65363240; called by muse, mutect2, varscan2
- OSBP | c.1252A>G p.N418D | Missense Mutation (SNP) | VAF 21/310 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55660815; called by muse, mutect2
- OSBPL8 | c.1048del p.S350Vfs*25 | Frame Shift Del (DEL) | VAF 139/367 reads (38%) | catalogued as COSV53884487; called by mutect2, pindel, varscan2
- P4HB | c.1160del p.N387Tfs*118 | Frame Shift Del (DEL) | VAF 40/96 reads (42%) | catalogued as rs763394045; called by mutect2, varscan2
- PACS1 | c.444G>T p.Q148H | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57695992; called by muse, mutect2, varscan2
- PAX1 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.219); catalogued as rs376309924, COSV68272440; called by muse, mutect2, varscan2
- PCARE | c.3605G>A p.R1202Q | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.053); catalogued as rs200071634; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHA10 | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.168); catalogued as COSV56475422; called by muse, mutect2, varscan2
- PCDHA12 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56475443; called by muse, mutect2, varscan2
- PCDHB15 | c.1681G>A p.V561M | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as rs1450297271, COSV50858134; called by muse, mutect2, varscan2
- PCNX1 | c.5588A>G p.Q1863R | Missense Mutation (SNP) | VAF 82/196 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53088760; called by muse, mutect2, varscan2
- PCSK5 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65082917; called by muse, mutect2, varscan2
- PCSK5 | c.1010G>T p.S337I | Missense Mutation (SNP) | VAF 78/171 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65082927; called by muse, mutect2, varscan2
- PDGFRB | c.2755C>T p.R919W | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs550187329, COSV55800310; called by muse, mutect2, varscan2
- PDZD2 | c.5528del p.K1843Rfs*31 | Frame Shift Del (DEL) | VAF 41/104 reads (39%) | catalogued as rs1184879635; called by mutect2, pindel, varscan2
- PDZD3 | c.572C>T p.T191I (on ENST00000531114; = p.T125I on NM_024791.4) | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.53); PolyPhen benign (0.046); catalogued as rs1240929700, COSV52701238; called by muse, mutect2, varscan2
- PEF1 | c.448T>C p.S150P | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.856); catalogued as COSV65483307; called by muse, mutect2, varscan2
- PGAP4 | c.295del p.R99Gfs*5 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | catalogued as rs765092936; called by mutect2, pindel, varscan2
- PGC | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs551237165, COSV63122114; called by muse, mutect2, varscan2
- PHACTR4 | c.279G>T p.E93D (on ENST00000373839 / NM_001350159.2; = p.E103D on NM_023923.4) | Missense Mutation (SNP) | VAF 5/117 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV65783068; called by muse, mutect2
- PHGDH | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1432614987, COSV65570269; called by muse, mutect2, varscan2
- PHLDB1 | c.3568G>A p.V1190I | Missense Mutation (SNP) | VAF 82/188 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as rs1250956741, COSV61876243; called by muse, mutect2, varscan2
- PIP4K2A | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.088); catalogued as COSV60539847; called by muse, mutect2, varscan2
- PITPNM1 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs751769016, COSV62707240; called by muse, mutect2, varscan2
- PKD1 | c.1964C>T p.P655L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs758548334, COSV51910043; called by muse, mutect2, varscan2
- PKD1L1 | c.3863G>A p.R1288H | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.089); catalogued as rs573425324, COSV56957442; called by muse, mutect2, varscan2
- PLAUR | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV55388355; called by muse, mutect2, varscan2
- PLK4 | c.2320G>T p.E774* | Nonsense Mutation (SNP) | VAF 42/114 reads (37%) | catalogued as COSV54636169, COSV99584653; called by muse, varscan2
- PMM2 | c.97C>T p.Q33* | Nonsense Mutation (SNP) | VAF 57/146 reads (39%) | catalogued as rs149530060; called by muse, mutect2, varscan2
- PNPLA6 | c.2024G>A p.R675H (on ENST00000414982 / NM_001166111.2; = p.R627H on NM_006702.5) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV55373192; called by muse, mutect2, varscan2
- PNPLA7 | c.3522del p.I1175Sfs*148 | Frame Shift Del (DEL) | VAF 9/18 reads (50%) | catalogued as rs761459630; called by mutect2, pindel, varscan2
- POLD1 | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.315); catalogued as COSV70953964; called by muse, mutect2, varscan2
- POLR2H | c.252-1G>T p.X84_splice | Splice Site (SNP) | VAF 32/100 reads (32%) | catalogued as COSV56177429; called by muse, mutect2, varscan2
- PPEF1 | c.409C>T p.H137Y | Missense Mutation (SNP) | VAF 75/186 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1363845242, COSV62995019; called by muse, mutect2, varscan2
- PPFIA3 | c.1094T>C p.L365P | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as COSV61949251; called by muse, mutect2, varscan2
- PPP1R13L | c.274G>T p.G92C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); catalogued as COSV62907814; called by muse, mutect2, varscan2
- PPP2R5A | c.*7del | Frame Shift Del (DEL) | VAF 24/56 reads (43%) | catalogued as rs540232176; called by mutect2, varscan2
- PPP6R2 | c.349A>G p.N117D | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV53289677, COSV53290893; called by muse, mutect2, varscan2
- PRDM11 | c.380del p.P127Rfs*40 (on ENST00000530656 / NM_001359633.1; = p.P93Rfs*40 on NM_001256695.1) | Frame Shift Del (DEL) | VAF 24/63 reads (38%) | catalogued as COSV55440445; called by mutect2, pindel, varscan2
- PRR16 | c.830del p.P277Lfs*20 (on ENST00000407149 / NM_001300783.2; = p.P254Lfs*20 on NM_016644.2) | Frame Shift Del (DEL) | VAF 30/74 reads (41%) | catalogued as COSV65401020; called by mutect2, pindel, varscan2
- PRRG1 | c.401dup p.P135Tfs*3 | Frame Shift Ins (INS) | VAF 87/244 reads (36%) | catalogued as rs781858060, COSV66158042; called by mutect2, varscan2
- PRSS54 | c.919G>T p.G307C | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV54684927; called by muse, mutect2
- PRTG | c.1808C>T p.S603L | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66836608, COSV66840470; called by muse, mutect2, varscan2
- PTK7 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV57846113; called by muse, mutect2, varscan2
- PTPRS | c.3223C>G p.L1075V | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53608855; called by muse, mutect2, varscan2
- QRICH1 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.076); catalogued as COSV62614292; called by muse, mutect2, varscan2
- QRICH2 | c.4910C>T p.P1637L | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs537326804, COSV53150518; called by muse, mutect2, varscan2
- QSER1 | c.2266C>T p.R756C (on ENST00000399302; = p.R885C on NM_001076786.3) | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as rs201421273; called by muse, mutect2, varscan2
- R3HCC1L | c.750G>A p.M250I | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV54398751; called by muse, mutect2, varscan2
- RAD51AP2 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 98/210 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.028); catalogued as rs1442061223, COSV67587247; called by muse, mutect2, varscan2
- RALGAPA1 | c.4283G>A p.C1428Y | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV51875405; called by muse, mutect2
- RASSF2 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.714); catalogued as rs755156690, COSV65081598; called by muse, mutect2, varscan2
- RBBP6 | c.3334_3336del p.K1112del | In Frame Del (DEL) | VAF 20/48 reads (42%) | catalogued as rs752572318; called by pindel, varscan2
- RBL2 | c.2975G>T p.G992V | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV50872792; called by muse, mutect2, varscan2
- RBM41 | c.806A>C p.K269T | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.22); catalogued as COSV52562017; called by muse, mutect2, varscan2
- RGPD1 | c.1293G>A p.W431* (on ENST00000409776; = p.W439* on NM_001024457.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 65/354 reads (18%) | catalogued as rs775950203, COSV101233648; called by muse, mutect2, varscan2
- RHOT2 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs1429906554, COSV53466120; called by muse, mutect2, varscan2
- RIMBP2 | c.2068A>G p.S690G | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV55463493; called by muse, mutect2, varscan2
- RIMS1 | c.3040T>C p.S1014P | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.764); catalogued as COSV53437058; called by muse, mutect2, varscan2
- RITA1 | c.222_223insT p.G75Wfs*7 | Frame Shift Ins (INS) | VAF 27/56 reads (48%) | catalogued as COSV100014073; called by mutect2, pindel, varscan2
- RNF103 | c.1383G>A p.W461* | Nonsense Mutation (SNP) | VAF 56/143 reads (39%) | catalogued as COSV52893501; called by muse, mutect2, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 64/130 reads (49%) | catalogued as rs757038390; called by mutect2, varscan2
- RNF40 | c.2811G>T p.E937D | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61213362; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 39/78 reads (50%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS25 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 114/259 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1034647326, COSV57722105; called by muse, mutect2, varscan2
- RSF1 | c.3263G>A p.R1088H | Missense Mutation (SNP) | VAF 97/210 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765155596, COSV57836052; called by muse, mutect2, varscan2
- RTL3 | c.350C>A p.P117H | Missense Mutation (SNP) | VAF 79/180 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.431); catalogued as COSV58182973; called by muse, mutect2, varscan2
- RTN3 | c.3089del p.K1030Rfs*67 (on ENST00000377819 / NM_001265589.2; = p.K234Rfs*67 on NM_006054.4) | Frame Shift Del (DEL) | VAF 52/114 reads (46%) | catalogued as rs747510098; called by mutect2, varscan2
- RUSF1 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs185844277; called by muse, mutect2, varscan2
- S100A12 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV64198959; called by muse, mutect2, varscan2
- S1PR5 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV61013268; called by muse, mutect2, varscan2
- SBNO2 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs201064922, COSV62318484; called by mutect2, varscan2
- SBNO2 | c.1039G>A p.V347I | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as rs753072881, COSV62318495; called by muse, mutect2, varscan2
- SDHB | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as rs1557746669, COSV64964776; called by muse, mutect2, varscan2
- SEC16A | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV51521128; called by muse, mutect2, varscan2
- SEC23IP | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); catalogued as COSV64830623; called by muse, mutect2
- SEC63 | c.1084T>C p.S362P | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV64598434; called by muse, mutect2, varscan2
- SEMA3E | c.1458G>T p.K486N | Missense Mutation (SNP) | VAF 102/271 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57078298; called by muse, varscan2
- SERPINE3 | c.808dup p.L270Pfs*33 | Frame Shift Ins (INS) | VAF 41/120 reads (34%) | catalogued as rs753981280; called by mutect2, pindel, varscan2
- SGK1 | c.693T>A p.D231E | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52804425; called by muse, mutect2
- SH2D4B | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754483761, COSV57892316; called by muse, mutect2, varscan2
- SH3TC1 | c.911T>C p.L304P | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV55280911; called by muse, mutect2, varscan2
- SHC2 | c.1586C>A p.P529H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV52743574; called by mutect2, varscan2
- SIN3A | c.1664G>T p.G555V | Missense Mutation (SNP) | VAF 75/163 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100845216, COSV64581605; called by muse, mutect2, varscan2
- SIN3A | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 89/225 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752788557, COSV64581612; called by muse, mutect2, varscan2
- SLC12A4 | c.1460G>A p.G487D | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57925100; called by muse, mutect2, varscan2
- SLC18A1 | c.379C>T p.Q127* | Nonsense Mutation (SNP) | VAF 80/203 reads (39%) | catalogued as rs566102024, COSV52346429; called by muse, mutect2, varscan2
- SLC22A6 | c.777del p.F259Lfs*27 | Frame Shift Del (DEL) | VAF 21/60 reads (35%) | catalogued as rs749849908; called by mutect2, pindel, varscan2
- SLC25A53 | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.444); catalogued as COSV62458260; called by muse, mutect2
- SLC26A1 | c.1762G>A p.A588T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as COSV56101273; called by muse, mutect2, varscan2
- SLC26A9 | c.1567-2A>G p.X523_splice | Splice Site (SNP) | VAF 116/283 reads (41%) | catalogued as COSV61600656; called by muse, mutect2, varscan2
- SLC27A5 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as rs1055339487, COSV54017882; called by muse, mutect2
- SLC39A8 | c.852del p.E285Sfs*8 | Frame Shift Del (DEL) | VAF 77/194 reads (40%) | catalogued as rs1560527212; called by mutect2, pindel, varscan2
- SLC41A3 | c.1001C>T p.T334I | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV59986817; called by muse, mutect2, varscan2
- SLC45A4 | c.910C>T p.R304C (on ENST00000517878 / NM_001286646.2; = p.R253C on NM_001080431.2) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs141043038; called by muse, mutect2, varscan2
- SLC5A3 | c.995A>G p.N332S | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.121); catalogued as rs754849326, COSV62967519; called by muse, mutect2, varscan2
- SLC6A1 | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 80/169 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV55112981; called by muse, mutect2, varscan2
- SLC6A2 | c.1505G>A p.S502N | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.445); catalogued as COSV54912924; called by muse, mutect2, varscan2
- SLIT2 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.814); catalogued as COSV56558551; called by muse, mutect2, varscan2
- SLIT3 | c.1678C>T p.R560W | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767560268, COSV60591040; called by muse, mutect2, varscan2
- SLITRK3 | c.2056C>A p.L686M | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV53845351; called by muse, mutect2, varscan2
- SMG8 | c.962A>T p.Q321L | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.973); catalogued as COSV56283603; called by muse, mutect2, varscan2
- SOX7 | c.769del p.L257Wfs*14 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | catalogued as rs1478777952; called by mutect2, pindel, varscan2
- SP140L | c.473A>G p.D158G | Missense Mutation (SNP) | VAF 113/259 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV54740815; called by muse, mutect2, varscan2
- SPACA3 | c.20del p.G7Efs*4 | Frame Shift Del (DEL) | VAF 41/111 reads (37%) | catalogued as COSV52192854; called by mutect2, pindel, varscan2
- SPTBN1 | c.5836G>A p.V1946I | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.191); catalogued as COSV61685079; called by muse, mutect2, varscan2
- SPTBN2 | c.3886G>A p.E1296K | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59446142; called by muse, mutect2, varscan2
- SPTBN4 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV58943072; called by muse, mutect2, varscan2
- SRGAP3 | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV64530055; called by muse, mutect2, varscan2
- SRRM2 | c.3410G>T p.R1137M | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV57067727; called by muse, mutect2, varscan2
- SRRT | c.2276G>A p.R759H | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53814860, COSV99573665; called by muse, mutect2, varscan2
- SSTR5 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs200422161, COSV53511241; called by muse, mutect2, varscan2
- STAB1 | c.2914C>T p.R972W | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745991082, COSV58731711; called by muse, mutect2, varscan2
- STAB1 | c.3546+1G>A p.X1182_splice | Splice Site (SNP) | VAF 26/47 reads (55%) | catalogued as rs755851044, COSV58731719; called by muse, mutect2, varscan2
- STAMBPL1 | c.1214del p.K405Rfs*21 | Frame Shift Del (DEL) | VAF 52/130 reads (40%) | catalogued as rs752994755; called by mutect2, varscan2
- STARD4 | c.74A>G p.E25G | Missense Mutation (SNP) | VAF 11/279 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV56967177; called by muse, mutect2
- STX7 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 114/254 reads (45%) | catalogued as COSV63398173; called by muse, mutect2, varscan2
- STYX | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs1422791149, COSV63462498; called by muse, mutect2, varscan2
- SUFU | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV64013739; called by muse, mutect2
- SULT1A1 | c.449C>A p.P150H | Missense Mutation (SNP) | VAF 62/564 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV59086523; called by muse, mutect2, varscan2
- SUN3 | c.876del p.K292Nfs*9 | Frame Shift Del (DEL) | VAF 47/207 reads (23%) | catalogued as COSV52049484; called by mutect2, pindel, varscan2
- SUPT16H | c.3019G>A p.E1007K | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.905); catalogued as rs1189468427, COSV52844057; called by muse, mutect2, varscan2
- SUPT16H | c.2032G>T p.G678C | Missense Mutation (SNP) | VAF 77/162 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53522096; called by muse, mutect2, varscan2
- SYT6 | c.1313del p.P438Rfs*25 (on ENST00000610222 / NM_001366225.1; = p.P353Rfs*25 on NM_205848.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 95/241 reads (39%) | catalogued as rs1557731023, COSV101059699, COSV65774990; called by mutect2, pindel, varscan2
- SZT2 | c.5870G>T p.R1957M (on ENST00000634258 / NM_001365999.1; = p.R1900M on NM_015284.4) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV65167069; called by muse, mutect2, varscan2
- TACC2 | c.5919del p.E1974Kfs*57 (on ENST00000334433; = p.E52Kfs*57 on NM_006997.4) | Frame Shift Del (DEL) | VAF 53/132 reads (40%) | catalogued as rs1565571647; called by mutect2, pindel, varscan2
- TACC3 | c.1554G>T p.L518F | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV57602588; called by muse, mutect2, varscan2
- TAF1 | c.3475T>C p.Y1159H (on ENST00000373790 / NM_138923.4; = p.Y1180H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as COSV52106796; called by muse, mutect2, varscan2
- TAF1C | c.993G>T p.Q331H | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58984410; called by muse, mutect2, varscan2
- TAF1L | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.113); catalogued as COSV54256461, COSV54268613; called by muse, mutect2
- TAF6 | c.778A>G p.S260G | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as rs748917815, COSV59840488; called by muse, mutect2, varscan2
- TAOK1 | c.2495G>A p.R832H | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs773046296, COSV55587785; called by muse, mutect2
- TARBP2 | c.565C>T p.R189C (on ENST00000266987 / NM_134323.2; = p.R168C on NM_004178.4) | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1340168203, COSV57198937; called by muse, mutect2, varscan2
- TASOR | c.3860A>T p.N1287I (on ENST00000355628 / NM_001365636.2; = p.N911I on NM_015224.3) | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs199831929, COSV100843413, COSV62926666; called by muse, mutect2, varscan2
- TBC1D2B | c.1981G>A p.A661T | Missense Mutation (SNP) | VAF 95/203 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV56038030; called by muse, mutect2, varscan2
- TCERG1 | c.1881dup p.R628Tfs*6 | Frame Shift Ins (INS) | VAF 14/39 reads (36%) | catalogued as rs751330927; called by mutect2, varscan2
- TCF25 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.863); catalogued as rs762453450, COSV54524084; called by muse, mutect2, varscan2
- TCF7L1 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV56395891; called by muse, mutect2, varscan2
- TCP1 | c.706T>C p.C236R | Missense Mutation (SNP) | VAF 97/226 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV58457350; called by muse, mutect2, varscan2
- TENT4B | c.850C>T p.P284S (on ENST00000561678 / NM_001365323.2; = p.P269S on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/194 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62546175; called by muse, varscan2
- TEX15 | c.4273A>G p.N1425D (on ENST00000256246; = p.N1808D on NM_001350162.2) | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV56341088; called by muse, mutect2, varscan2
- TFDP3 | c.785G>A p.S262N | Missense Mutation (SNP) | VAF 84/170 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as COSV59535756; called by muse, mutect2, varscan2
- TG | c.5093A>C p.Q1698P | Missense Mutation (SNP) | VAF 77/154 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV55064219; called by muse, mutect2, varscan2
- TGM6 | c.1024C>T p.R342W | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs150566697, COSV99172153; called by muse, mutect2, varscan2
- THBS2 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779901810, COSV64676933; called by muse, mutect2, varscan2
- THEMIS | c.455G>A p.C152Y | Missense Mutation (SNP) | VAF 73/153 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64069021; called by muse, mutect2, varscan2
- THOC1 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV55273642; called by muse, mutect2, varscan2
- THSD4 | c.2542G>A p.G848R | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs745347350, COSV55960005; called by muse, mutect2, varscan2
- TICAM1 | c.1925del p.P642Hfs*50 | Frame Shift Del (DEL) | VAF 4/11 reads (36%) | catalogued as COSV50235787; called by mutect2, varscan2
- TICAM1 | c.1061C>T p.T354I | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV50229380; called by muse, mutect2, varscan2
- TIE1 | c.671G>A p.C224Y | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV65248334; called by muse, mutect2, varscan2
- TLK2 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.931); catalogued as rs780493365, COSV58297024; called by muse, mutect2, varscan2
- TLN1 | c.5137A>G p.I1713V | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV59203729; called by muse, mutect2, varscan2
- TLR6 | c.1196C>T p.T399M | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs138968705; called by muse, mutect2, varscan2
- TM7SF3 | c.1484C>A p.A495D | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100544572, COSV58001225; called by muse, mutect2, varscan2
- TMA16 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.127); catalogued as COSV56807250; called by muse, mutect2, varscan2
- TMCO6 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV52798883; called by muse, varscan2
- TMEM121 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); catalogued as rs1189287802, COSV66796086; called by muse, varscan2
- TMEM217 | c.301A>G p.I101V | Missense Mutation (SNP) | VAF 81/185 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as COSV60824955; called by muse, mutect2, varscan2
- TMEM54 | c.449C>T p.T150I | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61275429; called by muse, mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 96/188 reads (51%) | catalogued as rs749773249; called by mutect2, varscan2
- TMPRSS11E | c.556C>A p.L186I | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV59517760, COSV59518229; called by muse, mutect2, varscan2
- TNC | c.6348C>A p.Y2116* | Nonsense Mutation (SNP) | VAF 52/136 reads (38%) | catalogued as COSV60779981; called by muse, mutect2, varscan2
- TNFRSF10A | c.425C>A p.P142H | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV55324319; called by muse, mutect2, varscan2
- TNIP1 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs925721048, COSV59303466; called by muse, mutect2, varscan2
- TNNI2 | c.71A>G p.Q24R | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.427); catalogued as COSV53288514; called by muse, mutect2
- TNS1 | c.2918del p.P973Rfs*13 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | catalogued as COSV50692006; called by mutect2, pindel, varscan2
- TP73 | c.1004del p.P335Lfs*10 | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | catalogued as COSV104414957; called by mutect2, pindel, varscan2
- TREM2 | c.59A>G p.N20S | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58293718; called by muse, mutect2, varscan2
- TRGJP | c.22dup p.I8Nfs*? | Frame Shift Ins (INS) | VAF 77/195 reads (39%) | catalogued as rs1210368960; called by mutect2, varscan2
- TRIM26 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.488); catalogued as rs1483374501, COSV68962820; called by muse, mutect2, varscan2
- TRIM41 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.267); catalogued as COSV59317282; called by muse, mutect2, varscan2
- TRIM50 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53090176; called by muse, mutect2, varscan2
- TRIO | c.8084C>T p.T2695M | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1032913640, COSV100702756, COSV59988447; called by muse, mutect2
- TRIO | c.8879C>T p.A2960V | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59988456; called by muse, mutect2, varscan2
- TRIOBP | c.5890C>T p.R1964C (on ENST00000644935 / NM_001039141.3; = p.R251C on NM_007032.5) | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs565618931, COSV58525686; called by muse, mutect2, varscan2
- TRO | c.4222G>T p.G1408C | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV51497130; called by muse, mutect2, varscan2
- TRPM4 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs758836432, COSV53259994; called by muse, mutect2, varscan2
- TTC38 | c.971G>A p.S324N | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.071); catalogued as COSV66843525; called by muse, mutect2, varscan2
- TUBGCP6 | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs762733400, COSV50536232; called by muse, mutect2, varscan2
- TUFM | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775427401, COSV57948256; called by muse, mutect2, varscan2
- TUT7 | c.4196C>T p.T1399I | Missense Mutation (SNP) | VAF 164/396 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs1456291217, COSV52893271; called by muse, varscan2
- UBA6 | c.2606G>A p.R869H | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771855418, COSV59173819; called by muse, mutect2, varscan2
- UBALD1 | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV52081713; called by muse, mutect2, varscan2
- UBE2E3 | c.528G>A p.A176= | Splice Region (SNP) | VAF 31/60 reads (52%) | catalogued as rs371595317, COSV101150516; called by muse, mutect2, varscan2
- UBIAD1 | c.311A>C p.Y104S | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100954957, COSV65147465; called by muse, mutect2, varscan2
- UBR4 | c.4588G>A p.D1530N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV64382426; called by muse, mutect2, varscan2
- UBR5 | c.4683G>T p.Q1561H | Missense Mutation (SNP) | VAF 91/210 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.598); catalogued as COSV55279433; called by muse, mutect2, varscan2
- UMODL1 | c.2669G>A p.R890K (on ENST00000408910 / NM_001004416.2; = p.R1018K on NM_173568.3) | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as COSV68569222; called by muse, mutect2, varscan2
- UNC13D | c.890G>A p.S297N | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.029); catalogued as COSV52882797; called by muse, mutect2, varscan2
- USP40 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1027543958, COSV52476719; called by muse, mutect2, varscan2
- VDR | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1000899385, COSV57466729; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VEZF1 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.044); catalogued as COSV51967326; called by muse, mutect2
- VPS35L | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV51976434; called by muse, mutect2, varscan2
- VSIG10 | c.1016del p.P339Lfs*7 | Frame Shift Del (DEL) | VAF 37/94 reads (39%) | catalogued as rs772031843; called by mutect2, pindel, varscan2
- WASHC2A | c.2915C>T p.A972V | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.124); catalogued as rs1335246930; called by muse, mutect2, varscan2
- WBP1 | c.552del p.H185Ifs*10 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as rs773064295, COSV51967888; called by pindel, varscan2
- WIPF1 | c.1402T>C p.Y468H | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV55811048; called by muse, mutect2
- WLS | c.1334T>C p.M445T | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV52036708; called by muse, mutect2, varscan2
- WRAP53 | c.1565del p.A522Gfs*26 | Frame Shift Del (DEL) | VAF 19/64 reads (30%) | catalogued as rs373064567, COSV56832921, COSV56833408; called by mutect2, pindel, varscan2
- XKRX | c.390G>T p.E130D | Missense Mutation (SNP) | VAF 99/209 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV60707257; called by muse, mutect2, varscan2
- XPO4 | c.2855C>T p.A952V | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.526); catalogued as rs1315856555, COSV55003494; called by muse, mutect2, varscan2
- YWHAG | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.624); catalogued as COSV56899639; called by muse, mutect2, varscan2
- ZBTB16 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1346143359, COSV60088891; called by muse, mutect2
- ZBTB39 | c.2129C>T p.P710L | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs747749909, COSV55627708; called by muse, mutect2, varscan2
- ZDHHC21 | c.72G>A p.W24* | Nonsense Mutation (SNP) | VAF 23/61 reads (38%) | catalogued as COSV66612050; called by muse, mutect2, varscan2
- ZFHX4 | c.1396C>G p.P466A | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.104); catalogued as COSV50480213; called by muse, mutect2, varscan2
- ZFR | c.1074del p.E359Kfs*4 | Frame Shift Del (DEL) | VAF 122/292 reads (42%) | catalogued as rs751974853; called by mutect2, varscan2
- ZGPAT | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs199674062, COSV58873340; called by mutect2, varscan2
- ZIC1 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51550317; called by muse, mutect2, varscan2
- ZMYM3 | c.4049G>A p.R1350H | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58735873; called by muse, mutect2, varscan2
- ZMYND10 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 113/254 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.245); catalogued as COSV51599862; called by muse, mutect2, varscan2
- ZNF382 | c.1547G>A p.G516D | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV53085752; called by muse, mutect2, varscan2
- ZNF461 | c.207G>T p.R69S | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.354); catalogued as COSV64452706; called by muse, mutect2, varscan2
- ZNF516 | c.2231C>A p.P744H | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); catalogued as COSV71586639; called by muse, mutect2, varscan2
- ZNF526 | c.881C>T p.T294M | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as rs559998555, COSV55898382; called by muse, mutect2
- ZNF559-ZNF177 | c.805T>C p.C269R | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1271795566, COSV58672298; called by muse, mutect2, varscan2
- ZNF574 | c.2495G>A p.R832H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV55901432; called by muse, mutect2, varscan2
- ZNF626 | c.345del p.G116Dfs*3 | Frame Shift Del (DEL) | VAF 32/143 reads (22%) | catalogued as rs782441698; called by mutect2, pindel, varscan2
- ZNF646 | c.3851G>A p.R1284H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs377163027; called by muse, mutect2, varscan2
- ZNF668 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.029); catalogued as rs1237585213, COSV56211130; called by muse, mutect2, varscan2
- ZNF681 | c.91A>G p.N31D | Missense Mutation (SNP) | VAF 86/210 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV68073330; called by muse, mutect2, varscan2
- ZNF74 | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs375125438; called by muse, mutect2, varscan2
- ZNF783 | c.395del p.P132Rfs*12 | Frame Shift Del (DEL) | VAF 43/117 reads (37%) | catalogued as rs746889769; called by mutect2, pindel, varscan2
- ZNF813 | c.1219G>A p.G407R | Missense Mutation (SNP) | VAF 73/155 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs764637390, COSV67175591; called by muse, mutect2, varscan2
- ZNF839 | c.1792A>G p.R598G (on ENST00000558850 / NM_001267827.1; = p.R714G on NM_018335.5) | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV51755964; called by muse, mutect2, varscan2
- ZSCAN29 | c.2038T>C p.C680R | Missense Mutation (SNP) | VAF 89/199 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67822076; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2848del p.H950Tfs*? | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- ADCY7 | c.2497_2499del p.K833del | In Frame Del (DEL) | VAF 36/92 reads (39%) | called by pindel, varscan2
- ANKRD40 | c.440del p.G147Afs*26 | Frame Shift Del (DEL) | VAF 29/65 reads (45%) | called by mutect2, pindel, varscan2
- ARAP2 | c.3221del p.N1074Mfs*11 | Frame Shift Del (DEL) | VAF 11/71 reads (15%) | called by mutect2, pindel, varscan2
- ARID1A | c.4881_4894del p.A1628Pfs*15 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | called by mutect2, pindel, varscan2
- ARID1B | c.2162del p.G721Afs*11 | Frame Shift Del (DEL) | VAF 25/107 reads (23%) | called by mutect2, pindel, varscan2
- ARSF | c.1511del p.P504Lfs*16 | Frame Shift Del (DEL) | VAF 83/189 reads (44%) | called by mutect2, pindel, varscan2
- ASGR2 | c.119del p.L40* | Frame Shift Del (DEL) | VAF 66/164 reads (40%) | called by mutect2, pindel, varscan2
- ASPM | c.5615del p.L1872* | Frame Shift Del (DEL) | VAF 31/96 reads (32%) | called by mutect2, pindel, varscan2
- ATF5 | c.454del p.Q152Sfs*72 | Frame Shift Del (DEL) | VAF 15/28 reads (54%) | called by mutect2, varscan2
- ATRIP | c.1033del p.L345Cfs*31 | Frame Shift Del (DEL) | VAF 40/108 reads (37%) | called by mutect2, pindel, varscan2
- BBS10 | c.1860del p.K620Nfs*12 | Frame Shift Del (DEL) | VAF 8/90 reads (9%) | called by mutect2, pindel
- BEST3 | c.1635del p.M546Wfs*42 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- BLOC1S5 | c.549del p.K183Nfs*24 | Frame Shift Del (DEL) | VAF 103/269 reads (38%) | called by mutect2, pindel, varscan2
- BOD1L1 | c.1707dup p.V570Sfs*15 | Frame Shift Ins (INS) | VAF 63/146 reads (43%) | called by mutect2, varscan2
- BSCL2 | c.782del p.G261Afs*75 | Frame Shift Del (DEL) | VAF 33/88 reads (38%) | called by mutect2, pindel, varscan2
- CAST | c.84dup p.Q29Tfs*8 (on ENST00000341926; = p.Q112Tfs*8 on NM_001750.7 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 38/114 reads (33%) | called by mutect2, pindel, varscan2
- CCDC80 | c.76del p.H26Mfs*27 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | called by mutect2, pindel, varscan2
- CDC42EP1 | c.20del p.G7Afs*7 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | called by mutect2, pindel, varscan2
- CEACAM7 | c.254del p.N85Ifs*2 | Frame Shift Del (DEL) | VAF 109/252 reads (43%) | called by mutect2, pindel, varscan2
- CIAO3 | c.436del p.I146* | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | called by mutect2, pindel, varscan2
- CSE1L | c.1037dup p.V347Gfs*5 | Frame Shift Ins (INS) | VAF 63/147 reads (43%) | called by mutect2, pindel, varscan2
- CST11 | c.313del p.Q105Rfs*27 | Frame Shift Del (DEL) | VAF 29/100 reads (29%) | called by mutect2, pindel, varscan2
- CTCF | c.610del p.T204Qfs*18 | Frame Shift Del (DEL) | VAF 28/74 reads (38%) | called by mutect2, pindel, varscan2
- CTCF | c.2070dup p.E691Rfs*5 | Frame Shift Ins (INS) | VAF 42/93 reads (45%) | called by mutect2, varscan2
- DCHS1 | c.2810dup p.G938Wfs*28 | Frame Shift Ins (INS) | VAF 41/95 reads (43%) | called by mutect2, pindel, varscan2
- DUSP14 | c.391_393del p.N131del | In Frame Del (DEL) | VAF 21/48 reads (44%) | called by mutect2, pindel, varscan2
- FAM83G | c.2224dup p.H742Pfs*62 | Frame Shift Ins (INS) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- FBXW7 | c.718del p.M240Cfs*14 (on ENST00000281708 / NM_001349798.2; = p.M160Cfs*14 on NM_018315.5) | Frame Shift Del (DEL) | VAF 88/264 reads (33%) | called by pindel, varscan2
- FCGBP | c.7769T>G p.L2590R | Missense Mutation (SNP) | VAF 42/329 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRRS1 | c.370dup p.T124Nfs*4 | Frame Shift Ins (INS) | VAF 78/214 reads (36%) | called by mutect2, varscan2
- FSTL5 | c.1287del p.F429Lfs*10 | Frame Shift Del (DEL) | VAF 85/228 reads (37%) | called by mutect2, pindel, varscan2
- FUBP3 | c.1184del p.P395Lfs*27 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- GFM1 | c.2238del p.G747Efs*17 | Frame Shift Del (DEL) | VAF 25/74 reads (34%) | called by mutect2, pindel, varscan2
- GNAZ | c.612del p.Q205Rfs*29 | Frame Shift Del (DEL) | VAF 30/86 reads (35%) | called by mutect2, varscan2
- HDLBP | c.3217del p.A1073Qfs*2 | Frame Shift Del (DEL) | VAF 78/213 reads (37%) | called by mutect2, pindel, varscan2
- HEY1 | c.543del p.T182Pfs*98 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | called by mutect2, pindel, varscan2
- HOXC10 | c.606del p.K203Sfs*51 | Frame Shift Del (DEL) | VAF 15/30 reads (50%) | called by mutect2, pindel, varscan2
- HPS1 | c.2095del p.L699Cfs*26 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 48/120 reads (40%) | called by mutect2, varscan2
- KANSL1L | c.245del p.L82* | Frame Shift Del (DEL) | VAF 90/246 reads (37%) | called by mutect2, pindel, varscan2
- KIAA0100 | c.3006del p.E1003Rfs*3 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | called by mutect2, pindel, varscan2
- KLF12 | c.991del p.S331Vfs*4 | Frame Shift Del (DEL) | VAF 74/203 reads (36%) | called by mutect2, pindel, varscan2
- KMT2A | c.3086dup p.A1030Gfs*9 | Frame Shift Ins (INS) | VAF 37/90 reads (41%) | called by mutect2, pindel, varscan2
- KNTC1 | c.4938del p.K1646Nfs*2 | Frame Shift Del (DEL) | VAF 37/87 reads (43%) | called by mutect2, varscan2
- LAMC3 | c.2336del p.P779Rfs*105 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | called by mutect2, pindel, varscan2
- LCP2 | c.1360del p.T454Qfs*73 | Frame Shift Del (DEL) | VAF 106/279 reads (38%) | called by mutect2, pindel, varscan2
- MAP7D3 | c.922del p.Q308Rfs*2 | Frame Shift Del (DEL) | VAF 44/136 reads (32%) | called by mutect2, varscan2
- MBD4 | c.744del p.G249Dfs*54 | Frame Shift Del (DEL) | VAF 104/268 reads (39%) | called by mutect2, pindel, varscan2
- MGAT5 | c.558del p.F186Lfs*43 | Frame Shift Del (DEL) | VAF 13/138 reads (9%) | called by mutect2, pindel, varscan2
- MPHOSPH8 | c.1376del p.N459Mfs*20 | Frame Shift Del (DEL) | VAF 38/78 reads (49%) | called by mutect2, varscan2
- MS4A13 | c.*3del | Frame Shift Del (DEL) | VAF 45/230 reads (20%) | called by mutect2, pindel, varscan2
- NAV2 | c.2486dup p.R830Sfs*11 (on ENST00000396087 / NM_001244963.2; = p.R807Sfs*11 on NM_145117.5) | Frame Shift Ins (INS) | VAF 9/32 reads (28%) | called by mutect2, pindel, varscan2
- NDST2 | c.572del p.L191Yfs*12 | Frame Shift Del (DEL) | VAF 23/76 reads (30%) | called by mutect2, pindel, varscan2
- NEIL1 | c.570del p.F191Lfs*20 | Frame Shift Del (DEL) | VAF 24/70 reads (34%) | called by mutect2, pindel, varscan2
- NFASC | c.494del p.P165Rfs*12 (on ENST00000339876 / NM_001378329.1; = p.P159Rfs*12 on NM_015090.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/96 reads (10%) | called by mutect2, pindel
- NSD1 | c.4591del p.M1531Cfs*43 | Frame Shift Del (DEL) | VAF 145/209 reads (69%) | called by mutect2, pindel, varscan2
- NUP214 | c.4133del p.P1378Rfs*3 | Frame Shift Del (DEL) | VAF 53/147 reads (36%) | called by mutect2, pindel, varscan2
- OR52N2 | c.776del p.F259Sfs*9 | Frame Shift Del (DEL) | VAF 33/249 reads (13%) | called by mutect2, pindel, varscan2
- PARP1 | c.1076dup p.E360Rfs*29 | Frame Shift Ins (INS) | VAF 32/95 reads (34%) | called by mutect2, pindel, varscan2
- PDE8A | c.806del p.K269Rfs*8 | Frame Shift Del (DEL) | VAF 12/119 reads (10%) | called by mutect2, pindel
- PDZD7 | c.1141dup p.E381Gfs*29 | Frame Shift Ins (INS) | VAF 4/8 reads (50%) | called by mutect2, varscan2
- PHF20L1 | c.965del p.N322Mfs*42 | Frame Shift Del (DEL) | VAF 23/65 reads (35%) | called by mutect2, varscan2
- PLA2G4D | c.2095del p.R699Gfs*73 | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | called by mutect2, pindel, varscan2
- PLEKHA6 | c.982del p.V328Yfs*172 | Frame Shift Del (DEL) | VAF 22/91 reads (24%) | called by mutect2, pindel, varscan2
- PLXDC1 | c.487del p.D163Tfs*2 | Frame Shift Del (DEL) | VAF 27/79 reads (34%) | called by mutect2, pindel, varscan2
- PLXNA1 | c.3051del p.Q1019Rfs*22 | Frame Shift Del (DEL) | VAF 26/72 reads (36%) | called by mutect2, pindel, varscan2
- POTEM | c.470T>C p.L157P | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by mutect2, varscan2
- POTEM | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 60/72 reads (83%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by mutect2, varscan2
- PPFIBP2 | c.210_211del p.R70Sfs*20 | Frame Shift Del (DEL) | VAF 38/109 reads (35%) | called by pindel, varscan2
- PSMD1 | c.372del p.K124Nfs*11 | Frame Shift Del (DEL) | VAF 37/98 reads (38%) | called by mutect2, varscan2
- PTCH1 | c.3606del p.S1203Afs*52 | Frame Shift Del (DEL) | VAF 37/92 reads (40%) | called by mutect2, pindel, varscan2
- PUS7 | c.668_669del p.E223Gfs*2 | Frame Shift Del (DEL) | VAF 110/322 reads (34%) | called by pindel, varscan2
- RBM27 | c.2488del p.R830Dfs*5 | Frame Shift Del (DEL) | VAF 44/129 reads (34%) | called by mutect2, pindel, varscan2
- ROBO1 | c.26del p.L9Wfs*3 | Frame Shift Del (DEL) | VAF 34/108 reads (31%) | called by mutect2, pindel, varscan2
- RPL22 | c.267del p.K89Nfs*3 | Frame Shift Del (DEL) | VAF 29/84 reads (35%) | called by mutect2, pindel, varscan2
- RPS4X | c.130del p.L44Sfs*5 | Frame Shift Del (DEL) | VAF 45/125 reads (36%) | called by mutect2, pindel, varscan2
- SH3KBP1 | c.1205del p.K402Sfs*28 | Frame Shift Del (DEL) | VAF 129/342 reads (38%) | called by mutect2, pindel, varscan2
- SHANK3 | c.3950C>T p.A1317V | Missense Mutation (SNP) | VAF 2/11 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by muse, mutect2
- SHLD2 | c.1962del p.G655Efs*4 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | called by mutect2, pindel
- SMAD7 | c.626del p.P209Lfs*115 | Frame Shift Del (DEL) | VAF 34/81 reads (42%) | called by mutect2, varscan2
- SPATA1 | c.658del p.S220Vfs*45 | Frame Shift Del (DEL) | VAF 46/140 reads (33%) | called by mutect2, pindel, varscan2
- SPSB2 | c.761del p.P254Lfs*3 | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | called by mutect2, pindel, varscan2
- STAT6 | c.1919del p.G640Vfs*9 | Frame Shift Del (DEL) | VAF 57/254 reads (22%) | called by mutect2, pindel, varscan2
- STXBP5L | c.1314dup p.Q439Tfs*5 | Frame Shift Ins (INS) | VAF 34/87 reads (39%) | called by mutect2, pindel, varscan2
- SUPT20H | c.808dup p.R270Kfs*11 (on ENST00000350612 / NM_001014286.3; = p.R271Kfs*11 on NM_017569.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 23/53 reads (43%) | called by mutect2, pindel, varscan2
- TET1 | c.6005del p.L2002Wfs*18 | Frame Shift Del (DEL) | VAF 42/123 reads (34%) | called by mutect2, pindel, varscan2
- TEX2 | c.2386del p.L796Cfs*29 (on ENST00000583097 / NM_001288733.2; = p.L803Cfs*29 on NM_018469.5) | Frame Shift Del (DEL) | VAF 24/79 reads (30%) | called by mutect2, pindel, varscan2
- TM9SF2 | c.155del p.K52Rfs*9 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- TSHZ3 | c.1637del p.G546Afs*14 | Frame Shift Del (DEL) | VAF 60/155 reads (39%) | called by mutect2, pindel, varscan2
- TSPAN19 | c.128del p.L43* | Frame Shift Del (DEL) | VAF 16/74 reads (22%) | called by mutect2, varscan2
- TTC33 | c.559del p.S187Vfs*7 | Frame Shift Del (DEL) | VAF 57/189 reads (30%) | called by mutect2, pindel, varscan2
- TTK | c.575del p.K192Sfs*18 | Frame Shift Del (DEL) | VAF 25/77 reads (32%) | called by mutect2, pindel, varscan2
- ULK1 | c.1722del p.T575Rfs*72 | Frame Shift Del (DEL) | VAF 18/45 reads (40%) | called by mutect2, pindel, varscan2
- USO1 | c.725del p.N242Tfs*18 | Frame Shift Del (DEL) | VAF 53/116 reads (46%) | called by mutect2, pindel, varscan2
- USP47 | c.3360del p.G1121Efs*22 (on ENST00000399455 / NM_001372095.1; = p.G1033Efs*22 on NM_017944.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 5/44 reads (11%) | called by mutect2, pindel, varscan2
- USP9X | c.82del p.L28Sfs*51 | Frame Shift Del (DEL) | VAF 22/101 reads (22%) | called by mutect2, pindel, varscan2
- WDR36 | c.2472del p.K824Nfs*6 | Frame Shift Del (DEL) | VAF 44/211 reads (21%) | called by mutect2, pindel, varscan2
- WHRN | c.836del p.K279Rfs*2 | Frame Shift Del (DEL) | VAF 28/79 reads (35%) | called by mutect2, pindel, varscan2
- ZNF23 | c.366del p.F122Lfs*35 | Frame Shift Del (DEL) | VAF 48/122 reads (39%) | called by mutect2, pindel, varscan2
- ZNF628 | c.2420del p.G807Vfs*9 | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | called by mutect2, pindel, varscan2
- ZNF862 | c.3241del p.Q1081Sfs*9 | Frame Shift Del (DEL) | VAF 19/51 reads (37%) | called by mutect2, pindel, varscan2
- ACTL9 | c.780C>T p.Y260= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV61004521; called by muse, mutect2, varscan2
- ACTN4 | c.384C>A p.S128= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV53142698, COSV99400695; called by muse, mutect2
- ADAL | c.294C>T p.G98= | Silent (SNP) | VAF 39/98 reads (40%) | catalogued as rs765890584, COSV67500037; called by muse, mutect2, varscan2
- ADAM17 | c.2016C>T p.I672= | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as rs753079319, COSV60397411; called by muse, mutect2, varscan2
- ADAM32 | c.996C>T p.D332= | Silent (SNP) | VAF 57/146 reads (39%) | catalogued as rs368424322; called by muse, mutect2, varscan2
- ADAM8 | c.603C>T p.Y201= | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as rs185462188, COSV69864253; called by muse, mutect2, varscan2
- ADAMTS14 | c.3570C>T p.G1190= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV64599422; called by muse, mutect2, varscan2
- ADGRB3 | c.2241T>C p.T747= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as COSV65381047; called by muse, mutect2, varscan2
- AFF2 | c.2208C>T p.C736= | Silent (SNP) | VAF 52/110 reads (47%) | catalogued as COSV53975214; called by muse, mutect2, varscan2
- ALDH18A1 | c.204G>A p.K68= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as rs768807587, COSV64662010; called by muse, mutect2, varscan2
- ALDH1A2 | c.81G>A p.P27= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs749073109, COSV51077969; called by muse, mutect2, varscan2
- ALDH7A1 | c.354C>T p.G118= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as rs149228266; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- ALPK1 | c.861C>A p.A287= | Silent (SNP) | VAF 31/91 reads (34%) | catalogued as COSV51581361; called by muse, mutect2, varscan2
- ALPK3 | c.210G>A p.Q70= | Silent (SNP) | VAF 36/66 reads (55%) | catalogued as COSV51928887; called by muse, mutect2, varscan2
- ANKMY1 | c.603G>A p.P201= | Silent (SNP) | VAF 60/222 reads (27%) | catalogued as rs200827415; called by muse, mutect2, varscan2
- APPL2 | c.1848T>C p.I616= | Silent (SNP) | VAF 74/153 reads (48%) | catalogued as COSV51587823; called by muse, mutect2, varscan2
- ARHGAP17 | c.2559T>C p.P853= (on ENST00000289968 / NM_001006634.3; = p.P775= on NM_018054.6) | Silent (SNP) | VAF 79/210 reads (38%) | catalogued as rs770119620, COSV51504621; called by muse, mutect2, varscan2
- ATP1A2 | c.1392A>G p.S464= | Silent (SNP) | VAF 40/86 reads (47%) | catalogued as COSV63402016; called by muse, mutect2, varscan2
- BAZ1A | c.3753C>T p.D1251= | Silent (SNP) | VAF 99/381 reads (26%) | catalogued as COSV62408826; called by muse, mutect2, varscan2
- BICRA | c.3774G>A p.S1258= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1462252827, COSV67603612; called by muse, mutect2, varscan2
- BRD2 | c.282G>A p.Q94= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV66372292; called by muse, mutect2, varscan2
- BRPF1 | c.1191C>T p.C397= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV57402990; called by muse, mutect2, varscan2
- BTD | c.1221T>G p.L407= | Silent (SNP) | VAF 66/138 reads (48%) | catalogued as COSV57728383; called by muse, mutect2, varscan2
- C1orf116 | c.1557G>A p.S519= | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as rs1179489476, COSV63943702; called by muse, mutect2
- C8orf82 | c.399C>T p.G133= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV52766645; called by muse, mutect2, varscan2
- CADM3 | c.507C>T p.D169= (on ENST00000368125 / NM_001127173.3; = p.D203= on NM_021189.5) | Silent (SNP) | VAF 7/102 reads (7%) | catalogued as COSV63683514; called by muse, mutect2
- CARNMT1 | c.975T>C p.I325= | Silent (SNP) | VAF 7/142 reads (5%) | catalogued as COSV65192999; called by muse, mutect2
- CCDC24 | c.468C>T p.S156= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV58842322; called by muse, mutect2, varscan2
- CD163L1 | c.1254C>T p.G418= | Silent (SNP) | VAF 53/121 reads (44%) | catalogued as COSV58010513; called by muse, mutect2, varscan2
- CDC5L | c.573T>C p.L191= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as COSV65175134; called by muse, mutect2, varscan2
- CEP152 | c.4203C>A p.T1401= (on ENST00000380950 / NM_001194998.2; = p.T1345= on NM_014985.4) | Silent (SNP) | VAF 20/193 reads (10%) | catalogued as COSV57856383; called by muse, mutect2, varscan2
- CFAP91 | c.1227C>A p.L409= | Silent (SNP) | VAF 8/135 reads (6%) | catalogued as COSV56338852; called by muse, mutect2
- CHID1 | c.729C>T p.H243= | Silent (SNP) | VAF 33/69 reads (48%) | catalogued as rs1181942112, COSV60257734; called by muse, mutect2, varscan2
- CHL1 | c.1149C>T p.P383= (on ENST00000397491 / NM_001253387.1; = p.P399= on NM_006614.4) | Silent (SNP) | VAF 9/168 reads (5%) | catalogued as COSV56585591; called by muse, mutect2
- CHRM3 | c.168C>T p.T56= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as rs747990640, COSV55078698; called by muse, mutect2
- CHRNG | c.33G>C p.L11= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV51317308, COSV51318611; called by muse, mutect2, varscan2
- CLTCL1 | c.4773C>T p.L1591= (on ENST00000427926 / NM_007098.4; = p.L1534= on NM_001835.4) | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as rs368882724; called by muse, mutect2, varscan2
- CNTNAP4 | c.276C>T p.T92= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as rs138220882, COSV56689011; called by muse, mutect2
- COL6A1 | c.2643G>T p.T881= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV62611308; called by muse, mutect2, varscan2
- CRACDL | c.235C>T p.L79= | Silent (SNP) | VAF 80/187 reads (43%) | catalogued as COSV101194008, COSV67406304; called by muse, mutect2, varscan2
- CRISPLD1 | c.681C>T p.C227= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV100082446, COSV51543853; called by muse, mutect2
- CRISPLD1 | c.1335C>T p.C445= | Silent (SNP) | VAF 58/132 reads (44%) | catalogued as COSV51543882; called by muse, mutect2, varscan2
- CSF1 | c.774C>T p.C258= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV60031844; called by muse, mutect2, varscan2
- CSMD1 | c.9423C>T p.R3141= (on ENST00000520002; = p.R3140= on NM_033225.6) | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs370498539; called by muse, mutect2
- CSMD1 | c.309G>A p.S103= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs747921329, COSV68164494; called by muse, mutect2, varscan2
- CSMD2 | c.1863C>T p.N621= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs138506777; called by muse, mutect2, varscan2
- CYGB | c.570G>A p.P190= | Silent (SNP) | VAF 43/94 reads (46%) | catalogued as rs767897368, COSV53149532; called by muse, mutect2, varscan2
- DBH | c.78G>T p.V26= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV55039559; called by mutect2, varscan2
- DPP8 | c.843T>C p.S281= (on ENST00000341861 / NM_001320875.2; = p.S265= on NM_017743.6) | Silent (SNP) | VAF 114/257 reads (44%) | catalogued as COSV55675656; called by muse, mutect2, varscan2
- DUSP21 | c.12C>T p.S4= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as COSV59133489; called by muse, mutect2, varscan2
- DYNC1H1 | c.11656C>T p.L3886= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV64134142; called by muse, mutect2, varscan2
- EDA2R | c.771G>T p.L257= | Silent (SNP) | VAF 49/82 reads (60%) | catalogued as COSV53630025, COSV53631551; called by muse, mutect2, varscan2
- ELMO1 | c.621G>A p.S207= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as rs148167670; called by muse, mutect2, varscan2
- ELOB | c.270C>T p.I90= | Silent (SNP) | VAF 44/107 reads (41%) | catalogued as rs758592257, COSV51939718; called by muse, mutect2, varscan2
- EML3 | c.1416C>T p.D472= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as COSV53903629; called by muse, mutect2, varscan2
- EPHA8 | c.2856T>C p.A952= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV51262359; called by muse, mutect2, varscan2
- ERICH1 | c.783C>T p.A261= | Silent (SNP) | VAF 88/196 reads (45%) | catalogued as rs529532827, COSV50637139; called by muse, mutect2, varscan2
- ESPL1 | c.5154C>T p.P1718= | Silent (SNP) | VAF 34/102 reads (33%) | catalogued as rs769120082, COSV57757130; called by muse, mutect2, varscan2
- ETS1 | c.303T>C p.N101= | Silent (SNP) | VAF 48/123 reads (39%) | catalogued as rs757838796, COSV60091550; called by muse, mutect2, varscan2
- FBXO25 | c.75T>C p.C25= | Silent (SNP) | VAF 69/165 reads (42%) | catalogued as COSV52335703; called by muse, mutect2, varscan2
- FBXW12 | c.66G>A p.L22= | Silent (SNP) | VAF 73/167 reads (44%) | catalogued as COSV56482687; called by muse, mutect2, varscan2
- FGL1 | c.177A>G p.E59= | Silent (SNP) | VAF 57/145 reads (39%) | catalogued as COSV67711702; called by muse, mutect2, varscan2
- FOXD4L1 | c.1191C>T p.G397= | Silent (SNP) | VAF 24/32 reads (75%) | catalogued as rs1317310012, COSV52072711; called by muse, mutect2, varscan2
- FUCA1 | c.1320C>T p.L440= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV65698611; called by muse, mutect2, varscan2
- FZD7 | c.15C>T p.G5= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs548996189, COSV53808052; called by muse, mutect2, varscan2
- G6PD | c.654C>T p.N218= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as rs1557230228, COSV63702199; called by muse, mutect2, varscan2
- GLT8D1 | c.864G>A p.L288= | Silent (SNP) | VAF 136/283 reads (48%) | catalogued as COSV56476460; called by muse, mutect2, varscan2
- GRM2 | c.633G>A p.A211= | Silent (SNP) | VAF 55/124 reads (44%) | catalogued as rs758585110, COSV56583093; called by muse, mutect2, varscan2
- GRXCR2 | c.591T>C p.C197= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as COSV65060619; called by muse, mutect2, varscan2
- GTSE1 | c.2019C>T p.C673= | Silent (SNP) | VAF 49/127 reads (39%) | catalogued as rs61737807; called by muse, mutect2, varscan2
- GZMM | c.555C>T p.S185= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV52741655; called by muse, mutect2, varscan2
- HIF1AN | c.747C>T p.Y249= | Silent (SNP) | VAF 53/101 reads (52%) | catalogued as rs369457092; called by muse, mutect2, varscan2
- HSD17B4 | c.501G>A p.K167= (on ENST00000414835 / NM_001199291.3; = p.K142= on NM_000414.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as rs758018890, COSV56333272; called by muse, mutect2, varscan2
- IDS | c.306G>A p.L102= | Silent (SNP) | VAF 48/146 reads (33%) | catalogued as COSV61711083; called by muse, mutect2, varscan2
- IFT140 | c.1029C>T p.T343= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs556379159, COSV68485725; called by muse, mutect2, varscan2
- IGHV3-53 | c.63G>A p.V21= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as rs556771598; called by muse, mutect2, varscan2
- IGHV3-66 | c.63G>A p.V21= | Silent (SNP) | VAF 50/300 reads (17%) | catalogued as rs1555573089; called by muse, varscan2
- IL1RAPL1 | c.1974C>T p.N658= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as rs746058514, COSV56235055; called by muse, mutect2, varscan2
- IL36A | c.147C>T p.C49= | Silent (SNP) | VAF 74/173 reads (43%) | catalogued as COSV52082578; called by muse, mutect2, varscan2
- ILDR1 | c.990C>A p.I330= (on ENST00000344209 / NM_001199799.2; = p.I286= on NM_175924.4) | Silent (SNP) | VAF 55/124 reads (44%) | catalogued as COSV56547295; called by muse, mutect2, varscan2
- INA | c.990C>T p.R330= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV63975514; called by muse, mutect2, varscan2
- ISLR2 | c.372G>A p.A124= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs780206482, COSV62301549; called by muse, mutect2, varscan2
- IZUMO1 | c.453C>T p.N151= | Silent (SNP) | VAF 59/144 reads (41%) | catalogued as COSV55802170; called by muse, mutect2, varscan2
- KANSL2 | c.1119C>T p.P373= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as rs763820416, COSV63479267; called by muse, mutect2, varscan2
- KAT2A | c.1197G>A p.A399= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs782764342, COSV56789030; called by muse, mutect2, varscan2
- KCNMB1 | c.390G>A p.Q130= | Silent (SNP) | VAF 50/116 reads (43%) | catalogued as COSV51131173; called by muse, mutect2, varscan2
- KCNN1 | c.1255C>A p.R419= | Silent (SNP) | VAF 16/115 reads (14%) | catalogued as COSV55836795, COSV55837632; called by muse, mutect2, varscan2
- KLHL20 | c.993C>T p.A331= | Silent (SNP) | VAF 83/171 reads (49%) | catalogued as COSV52939876; called by muse, mutect2, varscan2
- LEMD3 | c.1662G>A p.T554= | Silent (SNP) | VAF 6/104 reads (6%) | catalogued as rs1263905486, COSV57648175; called by muse, mutect2
- LIMK2 | c.792C>T p.H264= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs776548315, COSV59181262, COSV59184270; called by muse, mutect2, varscan2
- LOX | c.1023T>C p.T341= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as rs1471303009, COSV50236798; called by muse, mutect2, varscan2
- LRP2 | c.11562T>C p.C3854= | Silent (SNP) | VAF 70/151 reads (46%) | catalogued as COSV55539535; called by muse, mutect2, varscan2
- LRRC27 | c.1332C>T p.H444= | Silent (SNP) | VAF 35/89 reads (39%) | catalogued as rs1244498035, COSV63996009; called by muse, mutect2, varscan2
- LRTM1 | c.837G>A p.P279= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as rs150198745, COSV55554136; called by muse, mutect2, varscan2
- MAN2C1 | c.1888C>T p.L630= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV51226420; called by muse, mutect2, varscan2
- MAP3K5 | c.1773G>A p.V591= | Silent (SNP) | VAF 69/170 reads (41%) | catalogued as COSV62886732; called by muse, mutect2, varscan2
108 further variants in this file (0 protein-altering or splice-affecting, 83 silent, 25 other) are not listed here.
